Somatic mutation profile of tumor specimen TCGA-DU-A5TT-01A (aliquot TCGA-DU-A5TT-01A-11D-A289-08) from TCGA case TCGA-DU-A5TT, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 70.4 years (25,726 days).
Specimen TCGA-DU-A5TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac789aa3-1bcf-45dd-bd2b-01dbd1ff3691.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TT-10A (Blood Derived Normal), aliquot TCGA-DU-A5TT-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25145dd3-ff20-4789-ad64-b96ed0b6c061

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1708C>T p.R570W (on ENST00000372530 / NM_001198934.2; = p.R527W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376706540, COSV55085131; called by muse, mutect2, varscan2
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 61/134 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1_391del p.X126_splice | Splice Site (DEL) | VAF 16/40 reads (40%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACTRT3 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV57755265; called by muse, mutect2
- AKR1C1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs1138575, COSV66499175; called by muse, mutect2, varscan2
- BBS10 | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV53888936; called by muse, mutect2, varscan2
- C1R | c.697C>T p.R233C (on ENST00000536053 / NM_001354346.2; = p.R219C on NM_001733.7) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs370601700, COSV73293811; called by muse, mutect2, varscan2
- CBLN4 | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV50354283; called by muse, mutect2, varscan2
- CETN3 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51618220; called by muse, mutect2, varscan2
- CLEC9A | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs1470992449, COSV100872872, COSV63349582, COSV63351601; called by muse, mutect2, varscan2
- CREB3 | c.376_378del p.E126del | In Frame Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs769225730; called by pindel, varscan2
- DHX30 | c.3499G>C p.E1167Q (on ENST00000445061 / NM_138615.3; = p.E1128Q on NM_014966.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs1404830750, COSV53142464; called by muse, mutect2
- IFRD2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as rs587716301, COSV57115627; called by muse, mutect2, varscan2
- KCTD16 | c.324G>T p.R108S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV72576706, COSV72580489; called by muse, mutect2, varscan2
- KRTAP10-5 | c.293G>C p.C98S | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV59979088; called by muse, mutect2, varscan2
- LAIR2 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV56622994; called by muse, mutect2
- LIMCH1 | c.2411A>G p.E804G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58296104; called by muse, mutect2, varscan2
- MAGEB16 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV67874548; called by muse, mutect2, varscan2
- MAN2C1 | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV51243521; called by muse, mutect2, varscan2
- MGAT4C | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.69); catalogued as rs748796788, COSV59829726; called by muse, mutect2, varscan2
- NAV3 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760819848, COSV57110868; called by muse, mutect2, varscan2
- NIBAN1 | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62284647, COSV62287583; called by muse, mutect2, varscan2
- PDZRN4 | c.902A>G p.N301S (on ENST00000402685 / NM_001164595.2; = p.N43S on NM_013377.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.192); catalogued as COSV54216605; called by muse, mutect2, varscan2
- PDZRN4 | c.1045C>G p.L349V (on ENST00000402685 / NM_001164595.2; = p.L91V on NM_013377.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV54216634; called by muse, mutect2, varscan2
- PLEKHG5 | c.679C>T p.R227C (on ENST00000400915 / NM_001042663.3; = p.R190C on NM_020631.6) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs763551102, COSV61705821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTAFR | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.474); catalogued as COSV59538273; called by muse, mutect2, varscan2
- REPIN1 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101262676; called by muse, mutect2, varscan2
- RPS6KA6 | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV53126358; called by muse, mutect2, varscan2
- SIGLEC6 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs757685540, COSV58433672; called by muse, mutect2, varscan2
- SLITRK4 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62026046; called by muse, mutect2, varscan2
- STAT3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52893516; called by muse, mutect2, varscan2
- TLR2 | c.948G>T p.R316S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV52608054; called by muse, mutect2, varscan2
- UGT2B10 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55323375; called by muse, mutect2, varscan2
- ZSCAN18 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53737070; called by muse, mutect2, varscan2
- IL22RA1 | c.303G>A p.A101= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs536741554, COSV54628113; called by muse, mutect2, varscan2
- ITGAX | c.3036G>A p.A1012= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs148941060; called by muse, mutect2, varscan2
- ITGB2 | c.768G>A p.T256= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs201148219, COSV56613749; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MCHR2 | c.468C>T p.G156= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV56008474; called by muse, mutect2, varscan2
- MYO15A | c.1281C>T p.H427= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV52751087; called by muse, mutect2, varscan2
- NFASC | c.1851T>A p.T617= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV58379510; called by muse, mutect2, varscan2
- OR10R2 | c.147A>G p.V49= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as COSV63769510; called by muse, mutect2, varscan2
- OR13C8 | c.330G>A p.T110= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs984544900, COSV58610493; called by muse, mutect2, varscan2
- PGLYRP2 | c.777G>A p.T259= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs767287939, COSV52992120; called by muse, mutect2, varscan2
- PHKB | c.2175C>T p.H725= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs17853186, COSV54533552; called by muse, mutect2, varscan2
- SIGIRR | c.885T>C p.P295= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV58989955; called by muse, mutect2, varscan2
- GRM8 | c.727+48380C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1414578610, COSV58808115; called by muse, mutect2, varscan2
